Somatic mutation profile of tumor specimen MP2PRT-PATBVW-TMP1-A (aliquot MP2PRT-PATBVW-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATBVW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (883 days).
Specimen MP2PRT-PATBVW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0864db4c-1aa3-4401-86a1-e2a920975135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBVW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBVW-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ae89b77-4f69-4914-bf53-b10909462bf7

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 41/656 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as rs762028131, COSV58584897; ClinVar: uncertain significance; called by muse, mutect2
- DAPK1 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 71/652 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs760489928; called by muse, mutect2, varscan2
- GIGYF1 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51940578; called by muse, mutect2, varscan2
- PRKDC | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 19/273 reads (7%) | catalogued as rs867149509, COSV58046180; called by muse, mutect2
- FAM32A | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 34/996 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- IKZF3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 95/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBOAT4 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 39/604 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- PCDHA4 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 59/409 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOS2 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 65/651 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INKA2 | c.127C>T p.L43= | Silent (SNP) | VAF 54/473 reads (11%) | called by muse, mutect2, varscan2
- KIF2B | c.93C>T p.Y31= | Silent (SNP) | VAF 34/455 reads (7%) | catalogued as rs775762338; called by muse, mutect2
